Somatic mutation profile of cancer-model specimen HCM-BROD-0925-C71-85A (3D Neurosphere, passage 5; aliquot HCM-BROD-0925-C71-85A-01D-A88G-36), derived from the recurrence tumor of HCMI case HCM-BROD-0925-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.6 years (21,761 days).
Specimen HCM-BROD-0925-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db602ff9-ca38-44bb-bd0c-9817fd8e8d06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0925-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0925-C71-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fb571ba-5cac-42d9-a989-b466adf4639f

The open-access MAF lists 111 somatic variants for this specimen: 90 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 20, Frame Shift Del 8, In Frame Del 2, Splice Region 2, Frame Shift Ins 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 194/698 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs769696078, COSV51770322, COSV99297135; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 204/463 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 167/370 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB9 | c.1040G>A p.G347D | Missense Mutation (SNP) | VAF 137/317 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1288215924; called by muse, mutect2, varscan2
- ABCC5 | c.2107A>G p.R703G | Missense Mutation (SNP) | VAF 331/665 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs764155308; called by muse, mutect2, varscan2
- ACP5 | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 183/586 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as rs371116310; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY1 | c.2855C>T p.A952V | Missense Mutation (SNP) | VAF 156/467 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.123); catalogued as rs776377437; called by muse, mutect2, varscan2
- ATP8A2 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 132/296 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as rs546393054, COSV54957824; called by muse, mutect2, varscan2
- BHMG1 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 216/658 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.174); catalogued as rs1031410358, COSV104437583; called by muse, mutect2, varscan2
- CCDC170 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 88/216 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV104381633; called by muse, mutect2, varscan2
- CEACAM20 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 238/744 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as rs779566628, COSV57600755, COSV57602286; called by muse, varscan2
- CERS3 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 137/279 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs372884134; called by muse, mutect2, varscan2
- CERS6 | c.542A>G p.Y181C | Missense Mutation (SNP) | VAF 21/419 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1158666642; called by muse, mutect2
- CFTR | c.2065C>G p.Q689E | Missense Mutation (SNP) | VAF 98/424 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.901); catalogued as CM034787; called by muse, mutect2, varscan2
- COL1A2 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 98/301 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317653638, COSV99801057; called by muse, mutect2, varscan2
- CSMD2 | c.80C>T p.T27M | Missense Mutation (SNP) | VAF 146/284 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs754917632; called by muse, mutect2, varscan2
- DEFB104A | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs759852722; called by mutect2, varscan2
- DNAH11 | c.3980A>G p.K1327R | Missense Mutation (SNP) | VAF 125/409 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1282282699; called by muse, mutect2, varscan2
- DRD5 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 206/468 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs541886645, COSV58576883; called by muse, mutect2, varscan2
- FBXO41 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 218/470 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1430507971; called by muse, mutect2, varscan2
- FLT3 | c.121A>G p.K41E | Missense Mutation (SNP) | VAF 132/134 reads (99%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs139579569, COSV54074531; called by muse, mutect2, varscan2
- FRAS1 | c.8972C>T p.T2991M | Missense Mutation (SNP) | VAF 146/272 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376261766; called by muse, mutect2, varscan2
- HECTD4 | c.10037C>T p.P3346L | Missense Mutation (SNP) | VAF 305/627 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66391907; called by muse, mutect2, varscan2
- IGKV3-7 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 246/543 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as rs369766180; called by muse, mutect2, varscan2
- ITPKC | c.756dup p.Q253Tfs*4 | Frame Shift Ins (INS) | VAF 177/603 reads (29%) | catalogued as rs1484889842; called by mutect2, pindel, varscan2
- KBTBD11 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 215/344 reads (63%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.521); catalogued as COSV100207754; called by muse, mutect2, varscan2
- KDM4F | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 263/543 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1449602569; called by muse, mutect2, varscan2
- KRT14 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 140/301 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as rs369639773; called by muse, mutect2, varscan2
- MATN4 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 472/972 reads (49%) | PolyPhen probably damaging (0.999); catalogued as COSV59212902; called by muse, mutect2
- MIOX | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 221/409 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs146378961; called by muse, mutect2, varscan2
- NOTUM | c.594C>T p.N198= | Splice Region (SNP) | VAF 228/470 reads (49%) | catalogued as rs573529501, COSV68826884; called by muse, varscan2
- NPAP1 | c.985A>G p.K329E | Missense Mutation (SNP) | VAF 18/500 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV61504986; called by muse, mutect2
- PCDHGA4 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 310/709 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs375047889; called by muse, mutect2, varscan2
- PCED1B | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 255/525 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.907); catalogued as COSV71394910; called by muse, mutect2, varscan2
- PTEN | c.723del p.F241Lfs*15 | Frame Shift Del (DEL) | VAF 175/250 reads (70%) | catalogued as COSV64288616, COSV64291647; called by mutect2, pindel, varscan2
- RBPJ | c.1119del p.T374Qfs*16 | Frame Shift Del (DEL) | VAF 150/395 reads (38%) | catalogued as COSV100623533; called by mutect2, pindel, varscan2
- RFTN1 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 116/244 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs111844340, COSV61918876; called by muse, mutect2, varscan2
- RUNX1 | c.1196C>T p.P399L (on ENST00000344691 / NM_001001890.3; = p.P426L on NM_001754.5) | Missense Mutation (SNP) | VAF 232/482 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs1199937558; called by muse, mutect2, varscan2
- RYR1 | c.11770C>T p.R3924W | Missense Mutation (SNP) | VAF 177/579 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100614228; called by muse, mutect2, varscan2
- SEPTIN4 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 199/427 reads (47%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.006); catalogued as rs373119715; called by muse, mutect2, varscan2
- SERPINA4 | c.55C>A p.H19N | Missense Mutation (SNP) | VAF 200/434 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV100097327, COSV54070830; called by muse, mutect2, varscan2
- SLC26A3 | c.997G>A p.V333M | Missense Mutation (SNP) | VAF 181/519 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.223); catalogued as rs769800728; called by muse, mutect2, varscan2
- SPATA31D4 | c.2327C>G p.T776S | Missense Mutation (SNP) | VAF 20/690 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1467630250; called by muse, mutect2
- SSRP1 | c.1684C>T p.R562* | Nonsense Mutation (SNP) | VAF 257/504 reads (51%) | catalogued as rs1198818327, COSV53481842; called by muse, mutect2, varscan2
- SUN5 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 186/388 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.253); catalogued as rs759594105, COSV62180718; called by muse, mutect2, varscan2
- SYK | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 181/376 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs201994789, COSV65331383; called by muse, mutect2, varscan2
- SYT14 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 118/280 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as rs757948488, COSV55049423; called by muse, mutect2, varscan2
- TRPC6 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 172/365 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs770014593, COSV100723517, COSV60255510; called by muse, mutect2, varscan2
- TUSC3 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 134/269 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.148); catalogued as rs760970104, COSV65886822; called by muse, mutect2, varscan2
- ABHD4 | c.612G>T p.L204F | Missense Mutation (SNP) | VAF 187/428 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ALDH1A3 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 140/289 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARMH3 | c.1179_1180del p.C394Sfs*19 | Frame Shift Del (DEL) | VAF 124/196 reads (63%) | called by pindel, varscan2
- C15orf39 | c.578_580del p.G193del | In Frame Del (DEL) | VAF 296/636 reads (47%) | called by mutect2, pindel, varscan2
- CAVIN4 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 251/493 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC12 | c.17_19del p.A6del (on ENST00000425441 / NM_001277074.1; = p.A19del on NM_144716.5) | In Frame Del (DEL) | VAF 256/599 reads (43%) | called by mutect2, pindel, varscan2
- CDC42 | c.378T>G p.I126M | Missense Mutation (SNP) | VAF 194/394 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDKN2C | c.218T>A p.V73D | Missense Mutation (SNP) | VAF 276/531 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CELSR3 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 369/742 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, varscan2
- CERKL | c.1333G>T p.A445S (on ENST00000339098 / NM_001030311.2; = p.A419S on NM_201548.5) | Missense Mutation (SNP) | VAF 130/260 reads (50%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- CILP | c.2066T>A p.M689K | Missense Mutation (SNP) | VAF 199/429 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- DKK1 | c.241C>A p.Q81K | Missense Mutation (SNP) | VAF 136/138 reads (99%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXA2 | c.1003C>T p.P335S (on ENST00000377115 / NM_153675.3; = p.P341S on NM_021784.5) | Missense Mutation (SNP) | VAF 351/665 reads (53%) | SIFT tolerated (0.79); PolyPhen benign (0.01); called by muse, varscan2
- HCN4 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 416/882 reads (47%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HNRNPA1P48 | c.285A>T p.R95S | Missense Mutation (SNP) | VAF 76/528 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- HSD3B1 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 185/405 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- KMT2B | c.7547T>G p.L2516R | Missense Mutation (SNP) | VAF 20/594 reads (3%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.737); called by muse, mutect2
- MADD | c.824A>G p.E275G | Missense Mutation (SNP) | VAF 229/481 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MCHR1 | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 416/832 reads (50%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.419); called by muse, mutect2
- PABPC5 | c.195C>G p.N65K | Missense Mutation (SNP) | VAF 338/338 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBPJ | c.1285del p.V429Sfs*81 | Frame Shift Del (DEL) | VAF 216/526 reads (41%) | called by mutect2, pindel, varscan2
- RYR2 | c.3778C>A p.Q1260K | Missense Mutation (SNP) | VAF 156/287 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- S1PR1 | c.952A>G p.M318V | Missense Mutation (SNP) | VAF 231/447 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- SALL4 | c.364del p.H122Tfs*22 | Frame Shift Del (DEL) | VAF 239/575 reads (42%) | called by mutect2, pindel, varscan2
- SEMA3C | c.184G>T p.D62Y | Missense Mutation (SNP) | VAF 70/596 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHC3 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 415/829 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC46A2 | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 259/570 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- SLC4A9 | c.1634del p.G545Afs*4 (on ENST00000507527 / NM_001258428.2; = p.G521Afs*4 on NM_031467.3) | Frame Shift Del (DEL) | VAF 271/662 reads (41%) | called by mutect2, pindel, varscan2
- SLIT3 | c.2157C>G p.C719W | Missense Mutation (SNP) | VAF 257/535 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SMOC2 | c.1284C>T p.H428= (on ENST00000356284 / NM_001166412.2; = p.H439= on NM_022138.3) | Splice Region (SNP) | VAF 186/343 reads (54%) | called by muse, mutect2, varscan2
- SPARC | c.699_710delinsT p.W233Cfs*8 | Frame Shift Del (DEL) | VAF 126/352 reads (36%) | called by pindel, varscan2*
- SPATA31A1 | c.2038C>A p.Q680K | Missense Mutation (SNP) | VAF 328/792 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SRRM5 | c.1124G>A p.R375K | Missense Mutation (SNP) | VAF 205/681 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TMEM183A | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 220/479 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM29 | c.614dup p.A206Rfs*16 | Frame Shift Ins (INS) | VAF 401/924 reads (43%) | called by mutect2, pindel, varscan2
- UGT2B28 | c.1286T>G p.L429R | Missense Mutation (SNP) | VAF 89/90 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- URB2 | c.3851G>T p.G1284V | Missense Mutation (SNP) | VAF 188/413 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- WDR64 | c.1736T>C p.I579T | Missense Mutation (SNP) | VAF 116/236 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ZNF20 | c.388del p.H130Tfs*62 | Frame Shift Del (DEL) | VAF 169/602 reads (28%) | called by mutect2, pindel, varscan2
- ZNF30 | c.1597A>T p.I533F | Missense Mutation (SNP) | VAF 76/730 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.43); called by muse, mutect2
- ZNF681 | c.1742A>T p.K581M | Missense Mutation (SNP) | VAF 142/449 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDC27 | c.1788T>C p.V596= | Silent (SNP) | VAF 171/371 reads (46%) | catalogued as COSV50364484; called by muse, mutect2, varscan2
- DOCK3 | c.4488G>T p.V1496= | Silent (SNP) | VAF 132/288 reads (46%) | called by muse, mutect2, varscan2
- DOCK6 | c.3118C>T p.L1040= | Silent (SNP) | VAF 261/875 reads (30%) | called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.250T>C p.L84= | Silent (SNP) | VAF 126/444 reads (28%) | catalogued as rs1004216282; called by muse, mutect2, varscan2
- EYS | c.9429A>G p.K3143= (on ENST00000370621 / NM_001292009.1; = p.K3122= on NM_001142800.2) | Silent (SNP) | VAF 93/181 reads (51%) | called by muse, mutect2, varscan2
- GATA5 | c.195G>A p.A65= | Silent (SNP) | VAF 542/1089 reads (50%) | catalogued as rs782160947, COSV53346584; called by muse, mutect2, varscan2
- GCSAML | c.228C>T p.P76= | Silent (SNP) | VAF 174/382 reads (46%) | called by muse, mutect2, varscan2
- GDAP1L1 | c.963C>T p.T321= | Silent (SNP) | VAF 269/564 reads (48%) | catalogued as rs1217403755; called by muse, mutect2, varscan2
- GRIN3A | c.2619C>T p.Y873= | Silent (SNP) | VAF 121/242 reads (50%) | catalogued as rs147037319, CM099557; called by muse, mutect2, varscan2
- HSPA8 | c.1494G>A p.E498= | Silent (SNP) | VAF 137/287 reads (48%) | catalogued as rs1387335670, COSV99914216, COSV99914285; called by muse, mutect2, varscan2
- LMO2 | c.325C>A p.R109= (on ENST00000395833 / NM_001142315.2; = p.R178= on NM_005574.4) | Silent (SNP) | VAF 132/331 reads (40%) | catalogued as rs765694269, COSV57645420; called by muse, mutect2, varscan2
- MANBA | c.2211G>T p.L737= (on ENST00000642252; = p.L691= on NM_005908.4) | Silent (SNP) | VAF 152/275 reads (55%) | called by muse, mutect2, varscan2
- NUGGC | c.501G>A p.K167= | Silent (SNP) | VAF 182/438 reads (42%) | catalogued as COSV58437110; called by muse, mutect2
- OR51F1 | c.666C>T p.C222= | Silent (SNP) | VAF 158/306 reads (52%) | called by muse, mutect2, varscan2
- PCDHA5 | c.2025G>A p.P675= | Silent (SNP) | VAF 284/641 reads (44%) | catalogued as rs782129429, COSV65352484; called by muse, mutect2
- PWWP2A | c.360G>C p.P120= | Silent (SNP) | VAF 390/823 reads (47%) | called by muse, mutect2, varscan2
- SLC32A1 | c.939C>T p.I313= | Silent (SNP) | VAF 324/634 reads (51%) | catalogued as rs758524437; called by muse, mutect2, varscan2
- TFDP3 | c.819C>T p.D273= | Silent (SNP) | VAF 330/331 reads (100%) | catalogued as rs762868660, COSV59535768; called by muse, mutect2, varscan2
- TTF2 | c.2571G>A p.V857= | Silent (SNP) | VAF 124/292 reads (42%) | catalogued as COSV65632937; called by muse, mutect2, varscan2
- VSX2 | c.417T>C p.A139= | Silent (SNP) | VAF 46/569 reads (8%) | called by muse, mutect2
- COL6A2 | c.2462-2701C>T | Intron (SNP) | VAF 322/663 reads (49%) | catalogued as rs148646436, COSV56005113; called by muse, mutect2, varscan2
